Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U1, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U1-01A (Primary Tumor).

Histomorphology shows astrocytic tumor with increased cellularity and pleomorphism. Mitotic activity detectable. Proliferation focally up to 10%.

Diagnosis

Anaplastic astrocytoma WHO grade III

CCF ICD-O-3

Astrocytoma, grade III
9401/3

path

Astrocytoma, anaplastic
9401/3

Site Brain, supratentorial
C71.0

7/25/13

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 09c491a9-fc1f-417d-b624-55ff7b39ed3b (TCGA-S9-A6U1.400A5278-9C45-4FF9-AEF8-2155624D1168.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).